MMRF case MMRF_1338 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/508e0922-9b00-479d-adf4-12684cf1700a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 31 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 31.0 years (11,322 days); ISS stage: I; Days to last known disease status: 845 days (2.3 years); Days to last follow up: 845 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 12 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 852 days (2.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 852 days (2.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 845.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 13 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 298 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.027 mg/dL; Immunoglobulin G 21.5 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 151 µmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.8 g/dL.
- Day 115 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.142 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 9.67 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Glucose 4.35 mmol/L.
- Day 246 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 7.44 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 9.92 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 104 µmol/L; Calcium 2.43 mmol/L; Albumin 38.8 g/L.
- Day 323: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 17 µg/mL; Hemoglobin 10.2 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 386 (ECOG 0): M Protein 0.3 g/dL; Immunoglobulin G 5.46 g/L; Hemoglobin 9.49 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 6 g/dL; Glucose 4.79 mmol/L.
- Day 470 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 10.3 mmol/L; Leukocytes 3.9 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 92.8 µmol/L.
- Day 558 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.158 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 9.98 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 701 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 39.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.172 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 10.5 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.
- Day 825 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 75.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.154 mg/dL; Immunoglobulin G 9.44 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 10.2 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 48 g/L; Total Protein 6.5 g/dL; Glucose 4.51 mmol/L.

Other clinical attributes
- Day 13: Weight: 97 kg; Height: 180 cm.

Biospecimens (3 samples)
- Sample MMRF_1338_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 13 days.
- Sample MMRF_1338_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 13 days.
- Sample MMRF_1338_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 825 days (2.3 years).
